Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LN, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LN-01A (Primary Tumor).

FCD-0-3

Carcinoma, adrenal cortical
8370/3

Site: B Adrenal Gland cortex
0740

QID 4/6/13

Procedure: Right adrenalectomy.

Gross description: tumor is 168g; measuring 8.3 x 7 x 4.5cm

Diagnosis: Adrenal cortical carcinoma. Weiss score = 6. No lymph node metastasis.

IRB/AA Discrepancy		
Local Discrepancy History		
Qual/Syncronous History Noted		

Source: NCI Genomic Data Commons file 48fc7cde-e81a-435d-9565-4dbbf34c8daa (TCGA-OR-A5LN.92EE5592-2CEC-4F7C-BF7B-A0A2CEE5E169.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).